Gene-level copy-number profile of tumor specimen HTMCP-01-06-00594-01A from CGCI case HTMCP-01-06-00594, project CGCI-HTMCP-DLBCL (HIV+ Tumor Molecular Characterization Project - Diffuse Large B-Cell Lymphoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Diffuse large B-cell lymphoma, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 46.8 years (17,076 days).
Specimen HTMCP-01-06-00594-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 0c93cfca-3819-47fa-8d72-5d0c1aed5bff.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-01-06-00594-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,713 have no estimate.
https://portal.gdc.cancer.gov/files/a62762f9-dd71-4fa5-82c7-969cafaef72c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 534; copy number 1: 12,557; copy number 2: 43,593; copy number 3: 1,824; copy number 4: 402.

Homozygous deletions (total copy number 0; autosomes only): 22 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:12,847,377–12,947,580, 8 genes (within-gene range 0–1): HNRNPCL1, PRAMEF2, PRAMEF4, PRAMEF10, PRAMEF7, RNU6-1072P, PRAMEF29P, PRAMEF6.
- chr3:107,522,936–107,811,339, 1 gene: BBX.
- chr15:41,691,585–41,691,678, 1 gene (within-gene range 0–1): MIR626.
- chr16:71,637,835–71,835,932, 10 genes (within-gene range 0–1): PHLPP2, AC009097.1, RNU6-208P, SNORA70D, AC009097.4, AC009097.3, AP1G1, SNORD71, AC010653.3, AC010653.1.
- chr19:2,163,933–2,232,578, 2 genes (within-gene range 0–2): DOT1L, AC004490.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 10,792. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
